Somatic mutation profile of cancer-model specimen HCM-CSHL-0240-C18-85A (3D Organoid; aliquot HCM-CSHL-0240-C18-85A-01D-A78J-36), derived from the primary tumor of HCMI case HCM-CSHL-0240-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Medullary carcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 81.9 years (29,899 days).
Specimen HCM-CSHL-0240-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a0771ef-f863-4a7c-9c05-31decd709964.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0240-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-0240-C18-11A-11D-A78J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/790ccc14-8366-46cc-907c-fcbcaff6b379

The open-access MAF lists 2,711 somatic variants for this specimen: 1,831 protein-altering or splice-affecting, 513 silent, 367 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,233, Silent 513, Frame Shift Del 387, Intron 164, Frame Shift Ins 74, 3'UTR 66, Nonsense Mutation 57, 5'UTR 48, 5'Flank 36, Splice Region 34, RNA 33, Splice Site 25.

Variants (750 of 2,711; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALX4 | c.398del p.P133Rfs*48 | Frame Shift Del (DEL) | VAF 56/146 reads (38%) | catalogued as rs1085307637, COSV61327307; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- AXIN2 | c.1994dup p.N666Qfs*41 | Frame Shift Ins (INS) | VAF 120/297 reads (40%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 131/297 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRPF1 | c.2794del p.Q932Sfs*5 | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | catalogued as rs762904815, COSV57403691; ClinVar: pathogenic; called by mutect2, varscan2
- DDX3X | c.1123C>T p.R375C (on ENST00000399959; = p.R376C on NM_001356.5) | Missense Mutation (SNP) | VAF 131/279 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs796052231, CM158018, COSV67863865, COSV67864092; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXG1 | c.136del p.Q46Sfs*146 | Frame Shift Del (DEL) | VAF 71/176 reads (40%) | catalogued as rs587783629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FOXG1 | c.460dup p.E154Gfs*301 | Frame Shift Ins (INS) | VAF 71/164 reads (43%) | catalogued as rs398124204; ClinVar: pathogenic; called by mutect2, varscan2
- GLDC | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 182/380 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs386833587, CM042354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HNF1B | c.1561del p.Q521Sfs*70 | Frame Shift Del (DEL) | VAF 152/391 reads (39%) | catalogued as rs764042837; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KIF1A | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 178/357 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs797045655, COSV57486594; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 75/200 reads (38%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LBR | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 114/378 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs754049402; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MAP2K4 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 55/126 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62254615; called by muse, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 22/216 reads (10%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYH7 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 229/488 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1224554825, CM994128, COSV62520721; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO15A | c.1185del p.E396Rfs*48 | Frame Shift Del (DEL) | VAF 179/514 reads (35%) | catalogued as rs772536599; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- NDUFS7 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 46/454 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs11551664; ClinVar: likely pathogenic; called by muse, mutect2
- NEB | c.13705C>T p.R4569* | Nonsense Mutation (SNP) | VAF 30/63 reads (48%) | catalogued as rs754369875, CM1213409, COSV50859766; ClinVar: pathogenic; called by muse, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 29/250 reads (12%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 106/261 reads (41%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SPART | c.696del p.F232Lfs*2 | Frame Shift Del (DEL) | VAF 172/345 reads (50%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 133/291 reads (46%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455del p.P152Rfs*18 | Frame Shift Del (DEL) | VAF 71/306 reads (23%) | catalogued as rs730882019, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TRPV4 | c.1858G>A p.V620I | Missense Mutation (SNP) | VAF 316/664 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912633, CM083203, COSV55680649; ClinVar: pathogenic; called by muse, varscan2
- AAAS | c.771del p.R258Gfs*33 | Frame Shift Del (DEL) | VAF 245/623 reads (39%) | catalogued as rs1184877278, CD067140; called by mutect2, pindel, varscan2
- ABCA3 | c.3065G>A p.R1022Q | Missense Mutation (SNP) | VAF 189/355 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.055); catalogued as rs762690602, COSV100068696; called by muse, mutect2, varscan2
- ABCC6 | c.3320T>C p.V1107A | Missense Mutation (SNP) | VAF 104/217 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780276741; called by muse, mutect2, varscan2
- ABCF3 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 144/335 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs755216413, COSV53047219; called by muse, mutect2, varscan2
- ABCG4 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 87/211 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs758347342; called by muse, mutect2, varscan2
- ABLIM3 | c.1613A>G p.Y538C | Missense Mutation (SNP) | VAF 135/293 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.706); catalogued as rs904630965; called by muse, mutect2, varscan2
- ACLY | c.3088G>A p.G1030R | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1426806782; called by muse, mutect2, varscan2
- ACO2 | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs772704469, COSV53445251; called by muse, mutect2
- ACTA1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 163/496 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs1353303107, COSV64204113; called by muse, mutect2, varscan2
- ACTL7A | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 132/283 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.099); catalogued as rs367785686; called by muse, mutect2, varscan2
- ACTN2 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 188/287 reads (66%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs551141480, COSV63972194, COSV63975552; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACTN2 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 140/414 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV63978276; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 130/144 reads (90%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM23 | c.1465G>T p.G489* | Nonsense Mutation (SNP) | VAF 70/148 reads (47%) | catalogued as COSV100008254; called by muse, mutect2, varscan2
- ADAMTS2 | c.3521T>C p.V1174A | Missense Mutation (SNP) | VAF 16/590 reads (3%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV52366541; called by muse, mutect2
- ADAMTS7 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 225/444 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV66309539; called by muse, mutect2, varscan2
- ADARB2 | c.1908del p.F637Sfs*3 | Frame Shift Del (DEL) | VAF 81/228 reads (36%) | catalogued as COSV101184579; called by mutect2, pindel, varscan2
- ADGRB2 | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 139/300 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768585899; called by muse, mutect2, varscan2
- ADGRE5 | c.1139G>A p.R380H (on ENST00000242786 / NM_078481.4; = p.R287H on NM_001784.5) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs149991001; called by muse, mutect2
- ADGRF3 | c.2269G>A p.V757I (on ENST00000311519 / NM_001145168.1; = p.V558I on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 244/481 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs757696637; called by muse, mutect2, varscan2
- ADGRL2 | c.3545G>A p.G1182D | Missense Mutation (SNP) | VAF 120/312 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as COSV99589248; called by muse, varscan2
- ADGRV1 | c.11789T>C p.V3930A | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as rs761238357; called by muse, mutect2
- ADSS1 | c.197del p.X66_splice | Splice Site (DEL) | VAF 63/132 reads (48%) | catalogued as rs760706338; called by mutect2, pindel, varscan2
- AFF1 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 68/151 reads (45%) | catalogued as rs753451653, COSV100321078; called by muse, mutect2, varscan2
- AGAP3 | c.1136G>A p.G379D (on ENST00000622464; = p.G415D on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/213 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752343058; called by muse, mutect2, varscan2
- AGAP6 | c.326A>G p.H109R (on ENST00000374056 / NM_001365867.1; = p.H132R on NM_001077665.2) | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as COSV65017332; called by muse, mutect2
- AGBL5 | c.1266del p.E424Rfs*44 | Frame Shift Del (DEL) | VAF 100/271 reads (37%) | catalogued as rs747733044, COSV59935415; called by mutect2, pindel, varscan2
- AGO2 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 121/179 reads (68%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.874); catalogued as rs912917128; called by muse, mutect2, varscan2
- AHNAK2 | c.9795del p.D3266Tfs*36 | Frame Shift Del (DEL) | VAF 53/100 reads (53%) | catalogued as rs777248951, COSV60907891; called by mutect2, pindel, varscan2
- AHRR | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 183/345 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs775797513; called by muse, mutect2, varscan2
- AJM1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 105/183 reads (57%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs754098168; called by muse, varscan2
- AKAP17A | c.1822C>T p.R608W | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs375125397, COSV100002218; called by muse, mutect2, varscan2
- AKAP3 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 118/251 reads (47%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs200377453, COSV57415556; called by muse, mutect2, varscan2
- AKAP6 | c.3082G>A p.V1028I | Missense Mutation (SNP) | VAF 97/227 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs141386857, COSV55214164; called by muse, mutect2, varscan2
- AKAP9 | c.6977C>T p.T2326M (on ENST00000359028; = p.T2302M on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/155 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs368444006; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- AKT1 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 104/244 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.211); catalogued as rs369698909; called by muse, mutect2, varscan2
- ALDH5A1 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.011); catalogued as rs768533338; called by muse, mutect2, varscan2
- ALG11 | c.52del p.Y18Ifs*35 | Frame Shift Del (DEL) | VAF 112/321 reads (35%) | catalogued as COSV73000541; called by mutect2, pindel, varscan2
- ALG8 | c.206del p.P69Lfs*22 | Frame Shift Del (DEL) | VAF 99/247 reads (40%) | catalogued as CM098505; called by mutect2, pindel, varscan2
- ALKBH4 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs754692846; called by muse, mutect2, varscan2
- ALPK2 | c.83A>G p.D28G | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV64491866; called by muse, varscan2
- ALPP | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 139/564 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs1241480466; called by muse, varscan2
- AMER1 | c.2840C>T p.S947F | Missense Mutation (SNP) | VAF 71/132 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57656670; called by muse, mutect2, varscan2
- AMER3 | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.076); catalogued as rs777579863; called by muse, mutect2, varscan2
- AMIGO1 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 96/204 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100881075; called by muse, mutect2, varscan2
- ANAPC4 | c.1975C>T p.R659C | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs779976609; called by muse, mutect2, varscan2
- ANK3 | c.1898C>T p.T633M | Missense Mutation (SNP) | VAF 133/276 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753344992, COSV104383739; called by muse, mutect2, varscan2
- ANKRD11 | c.6005C>A p.S2002Y | Missense Mutation (SNP) | VAF 98/208 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99039934; called by muse, mutect2, varscan2
- ANKRD16 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs200993355, COSV51947535; called by muse, mutect2, varscan2
- ANKRD34A | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as rs1553761404, COSV60160896; called by muse, mutect2, varscan2
- ANKRD34A | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 134/202 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs782545703, COSV60161202; called by muse, mutect2, varscan2
- ANKRD36 | c.3446del p.K1149Rfs*17 | Frame Shift Del (DEL) | VAF 32/177 reads (18%) | catalogued as rs777704179; called by mutect2, pindel, varscan2
- ANKRD46 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs376278571; called by muse, varscan2
- ANKRD63 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 121/244 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as rs1464803596; called by muse, mutect2, varscan2
- ANO8 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 100/188 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs757084785, COSV50192062; called by muse, mutect2, varscan2
- AP5B1 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs372030130; called by muse, mutect2, varscan2
- APH1A | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52529934; called by muse, mutect2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 35/81 reads (43%) | catalogued as rs546686089; called by mutect2, varscan2
- APOL3 | c.886C>T p.R296C (on ENST00000349314 / NM_145640.2; = p.R225C on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 131/253 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs141623013; called by muse, mutect2, varscan2
- ARHGAP22 | c.1084G>A p.G362R | Missense Mutation (SNP) | VAF 36/292 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs927039629, COSV50936342; called by muse, mutect2, varscan2
- ARHGAP23 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as rs1455090989; called by muse, mutect2, varscan2
- ARHGAP23 | c.839G>A p.S280N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as rs1300357384; called by muse, varscan2
- ARHGAP23 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs775996184; called by muse, varscan2
- ARHGAP33 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 141/311 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as rs773138268; called by muse, mutect2, varscan2
- ARHGAP33 | c.3254dup p.E1086Rfs*34 | Frame Shift Ins (INS) | VAF 78/179 reads (44%) | catalogued as rs762833509; called by mutect2, varscan2
- ARHGAP35 | c.2915G>A p.R972Q | Missense Mutation (SNP) | VAF 101/228 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.856); catalogued as rs776102282, COSV68335942; called by muse, mutect2, varscan2
- ARHGAP45 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 24/550 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV54027946; called by muse, mutect2
- ARHGAP45 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as rs761730903, COSV57431886; called by muse, mutect2, varscan2
- ARHGEF3 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 95/220 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs950370717; called by muse, mutect2, varscan2
- ARHGEF33 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 120/267 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.228); catalogued as rs554200497; called by muse, mutect2, varscan2
- ARHGEF40 | c.3749G>A p.G1250D | Missense Mutation (SNP) | VAF 146/321 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745722398; called by muse, mutect2, varscan2
- ARID4A | c.1266del p.D423Tfs*2 | Frame Shift Del (DEL) | VAF 61/148 reads (41%) | catalogued as rs776520069; called by mutect2, varscan2
- ARL13B | c.932del p.N311Ifs*6 (on ENST00000394222 / NM_001174150.2; = p.N204Ifs*6 on NM_144996.4) | Frame Shift Del (DEL) | VAF 60/144 reads (42%) | catalogued as rs750642821; called by mutect2, varscan2
- ARMCX6 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 114/434 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1180836922; called by muse, mutect2, varscan2
- ARPP21 | c.2146G>A p.V716M | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as rs762995319; called by muse, mutect2, varscan2
- ASB13 | c.20A>G p.D7G | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as rs1320507093; called by muse, mutect2, varscan2
- ASB17 | c.530del p.N177Tfs*7 | Frame Shift Del (DEL) | VAF 90/194 reads (46%) | catalogued as rs749460467; called by mutect2, varscan2
- ASB2 | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 99/192 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60112053; called by muse, mutect2, varscan2
- ASCL4 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 192/400 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV60816741; called by muse, mutect2, varscan2
- ASIC4 | c.287C>A p.P96H | Missense Mutation (SNP) | VAF 193/395 reads (49%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.999); catalogued as COSV61731524; called by muse, mutect2, varscan2
- ASPG | c.1075del p.E359Rfs*2 | Frame Shift Del (DEL) | VAF 137/343 reads (40%) | catalogued as COSV101496412; called by mutect2, pindel, varscan2
- ATP10A | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 207/431 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as rs1372051472; called by muse, mutect2, varscan2
- ATP13A1 | c.907-6G>A | Splice Region (SNP) | VAF 122/259 reads (47%) | catalogued as rs767187901; called by muse, mutect2, varscan2
- ATP8B2 | c.2747C>T p.T916I (on ENST00000672630; = p.T883I on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/450 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59248283; called by muse, mutect2
- ATRX | c.4795G>A p.G1599S | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64881575; called by muse, mutect2, varscan2
- AXL | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 96/214 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.04); catalogued as rs775611992; called by muse, mutect2, varscan2
- B3GNT8 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.84); catalogued as rs367663254; called by muse, mutect2, varscan2
- B3GNT9 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV54625749; called by muse, mutect2, varscan2
- B4GALT7 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 154/294 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs764639019, COSV50352584; called by muse, varscan2
- BAHCC1 | c.2706del p.M903Cfs*71 | Frame Shift Del (DEL) | VAF 111/246 reads (45%) | catalogued as COSV100311192; called by mutect2, pindel, varscan2
- BAZ2B | c.2166_2168del p.S723del | In Frame Del (DEL) | VAF 73/166 reads (44%) | catalogued as rs752085908; called by pindel, varscan2
- BCAS3 | c.1888C>T p.R630* (on ENST00000390652 / NM_001353144.2; = p.R615* on NM_017679.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 108/209 reads (52%) | catalogued as rs1416992531; called by muse, mutect2, varscan2
- BCL11B | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs1457974153; called by muse, varscan2
- BCL9L | c.3380del p.P1127Hfs*21 | Frame Shift Del (DEL) | VAF 61/140 reads (44%) | catalogued as rs751794665; called by mutect2, varscan2
- BCORL1 | c.4060C>T p.R1354W | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs146180952; called by muse, mutect2, varscan2
- BEST3 | c.1332del p.R445Gfs*40 | Frame Shift Del (DEL) | VAF 75/209 reads (36%) | catalogued as rs779566914, COSV58300788; called by mutect2, pindel, varscan2
- BICDL2 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 115/379 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs764803591, COSV54156544; called by muse, mutect2, varscan2
- BID | c.434G>A p.R145H (on ENST00000317361 / NM_197966.2; = p.R99H on NM_001196.4) | Missense Mutation (SNP) | VAF 87/207 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs370897535, COSV58008766; called by muse, mutect2, varscan2
- BIRC6 | c.8659G>A p.V2887M | Missense Mutation (SNP) | VAF 70/133 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs755972507; called by muse, mutect2, varscan2
- BMX | c.245T>A p.I82N | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100564274; called by muse, mutect2, varscan2
- BNC2 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 228/500 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.202); catalogued as rs1488921825; called by muse, mutect2, varscan2
- BRD1 | c.1771G>A p.V591M | Missense Mutation (SNP) | VAF 78/326 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768796290; called by muse, mutect2, varscan2
- BRPF1 | c.1343C>T p.T448M | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as rs753525669; called by muse, mutect2, varscan2
- BRPF1 | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 116/244 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs768402081, COSV57407406; called by muse, mutect2, varscan2
- BRSK1 | c.347del p.G116Vfs*8 | Frame Shift Del (DEL) | VAF 69/162 reads (43%) | catalogued as rs776865070; called by mutect2, pindel, varscan2
- BTF3L4 | c.135dup p.L46Tfs*5 | Frame Shift Ins (INS) | VAF 63/144 reads (44%) | catalogued as rs1558005082; called by mutect2, varscan2
- BTN2A1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 127/297 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.265); catalogued as COSV57005840; called by muse, varscan2
- BUB3 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV64363991; called by muse, mutect2
- C11orf42 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as rs781116265, COSV56410011; called by muse, mutect2, varscan2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 70/191 reads (37%) | catalogued as COSV62298237; called by mutect2, pindel, varscan2
- C17orf80 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 210/451 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs369548621; called by muse, mutect2, varscan2
- C1QTNF4 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1372789544; called by muse, mutect2, varscan2
- C1QTNF9 | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs1419089027; called by muse, mutect2, varscan2
- C2 | c.2249dup p.L750Ffs*39 | Frame Shift Ins (INS) | VAF 158/406 reads (39%) | catalogued as rs774429190; called by mutect2, pindel, varscan2
- C4orf54 | c.990del p.G331Efs*45 | Frame Shift Del (DEL) | VAF 35/111 reads (32%) | catalogued as rs1388862189; called by mutect2, pindel, varscan2
- C6 | c.2567G>A p.S856N | Missense Mutation (SNP) | VAF 198/406 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1416773804, COSV54712077; called by muse, mutect2, varscan2
- C8orf74 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1267914932, COSV58755007; called by muse, mutect2, varscan2
- C9orf50 | c.170del p.G57Afs*87 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as rs1423916757, COSV65252410; called by mutect2, pindel, varscan2
- CABIN1 | c.4109C>T p.T1370M | Missense Mutation (SNP) | VAF 165/398 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.362); catalogued as rs761243312; called by muse, mutect2, varscan2
- CACNA1G | c.4390C>T p.R1464W | Missense Mutation (SNP) | VAF 88/200 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV61728654; called by muse, mutect2, varscan2
- CACNA1I | c.5744C>T p.S1915L | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.203); catalogued as rs374151542; called by muse, mutect2, varscan2
- CACNA1S | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 264/413 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs776209588; called by muse, mutect2, varscan2
- CAMSAP3 | c.2266T>C p.S756P | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.497); catalogued as rs939761601; called by muse, mutect2, varscan2
- CASP8 | c.1181C>T p.P394L (on ENST00000432109 / NM_033355.3; = p.P411L on NM_001228.4) | Missense Mutation (SNP) | VAF 164/308 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51846287, COSV51861191; called by muse, mutect2, varscan2
- CASS4 | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 104/204 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs371811746; called by muse, mutect2, varscan2
- CBX2 | c.587C>G p.P196R | Missense Mutation (SNP) | VAF 198/386 reads (51%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.457); catalogued as COSV53969489; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 57/128 reads (45%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC166 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1554616846; called by muse, mutect2, varscan2
- CCDC92 | c.801del p.I268Sfs*40 | Frame Shift Del (DEL) | VAF 97/188 reads (52%) | catalogued as rs773752200; called by mutect2, varscan2
- CD1D | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 240/684 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV63808559, COSV63810154; called by muse, mutect2, varscan2
- CD276 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 147/310 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as rs184115783; called by muse, mutect2, varscan2
- CD36 | c.1209G>T p.K403N | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV59211374; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 123/220 reads (56%) | catalogued as rs781937995, COSV99163893; called by mutect2, varscan2
- CD86 | c.203T>C p.V68A (on ENST00000330540 / NM_175862.5; = p.V62A on NM_006889.4) | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV100054135; called by muse, mutect2, varscan2
- CDC25B | c.721C>T p.R241W (on ENST00000245960 / NM_021873.3; = p.R227W on NM_004358.4) | Missense Mutation (SNP) | VAF 65/112 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs202222511; called by muse, mutect2, varscan2
- CDC40 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs760746039; called by muse, mutect2, varscan2
- CDC5L | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 107/242 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as rs145762260; called by muse, mutect2, varscan2
- CDH11 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs957826065, COSV51770412; called by muse, mutect2, varscan2
- CDH18 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99934222; called by muse, mutect2, varscan2
- CDH22 | c.1176del p.E393Sfs*24 | Frame Shift Del (DEL) | VAF 38/110 reads (35%) | catalogued as rs768497155, COSV64836926; called by mutect2, pindel
- CDH24 | c.714dup p.L239Afs*67 | Frame Shift Ins (INS) | VAF 129/276 reads (47%) | catalogued as rs765496989; called by mutect2, varscan2
- CDKL2 | c.222del p.K74Nfs*5 | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | catalogued as rs753353408; called by mutect2, varscan2
- CEBPZ | c.2885-3del | Splice Region (DEL) | VAF 28/72 reads (39%) | catalogued as rs375852685; called by mutect2, varscan2
- CENPC | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 159/309 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs371671240, COSV56623034; called by muse, mutect2, varscan2
- CEP112 | c.1655del p.K552Rfs*27 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as rs754269394; called by mutect2, pindel, varscan2
- CEP112 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs147020220, COSV67137724; called by muse, mutect2, varscan2
- CEP295 | c.1657dup p.T553Nfs*18 | Frame Shift Ins (INS) | VAF 57/121 reads (47%) | catalogued as rs749718914; called by mutect2, varscan2
- CEP97 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 133/315 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs889687328; called by muse, mutect2, varscan2
- CFAP46 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 148/351 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.363); catalogued as COSV63951418; called by muse, mutect2, varscan2
- CFAP74 | c.2912C>T p.T971M | Missense Mutation (SNP) | VAF 12/259 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as rs937664964; called by muse, mutect2
- CGAS | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs200213844; called by muse, varscan2
- CHD3 | c.1618dup p.R540Pfs*47 | Frame Shift Ins (INS) | VAF 72/282 reads (26%) | catalogued as rs747299117; called by mutect2, varscan2
- CHD5 | c.3407G>A p.R1136H | Missense Mutation (SNP) | VAF 121/207 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1162494442, COSV52418865; called by muse, mutect2, varscan2
- CHD5 | c.1659dup p.F554Lfs*2 | Frame Shift Ins (INS) | VAF 61/262 reads (23%) | catalogued as rs1419451052; called by mutect2, pindel, varscan2
- CHEK1 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 64/126 reads (51%) | catalogued as rs1486238508; called by muse, mutect2, varscan2
- CHFR | c.38C>A p.P13Q | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1407689006, COSV57173272; called by muse, mutect2, varscan2
- CHRD | c.2171C>T p.P724L | Missense Mutation (SNP) | VAF 298/614 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.788); catalogued as rs781476129; called by muse, mutect2, varscan2
- CHST5 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 88/181 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1454993446, COSV100291890; called by muse, mutect2, varscan2
- CIT | c.4790C>T p.T1597M | Missense Mutation (SNP) | VAF 139/293 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs773121506; called by muse, mutect2, varscan2
- CLDN23 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1331817599; called by muse, mutect2, varscan2
- CLSTN3 | c.2605C>T p.R869C | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750797901, COSV56938756; called by muse, mutect2
- CNEP1R1 | c.336+14del | Splice Region (DEL) | VAF 67/182 reads (37%) | catalogued as rs1006253245; called by mutect2, pindel, varscan2
- CNOT4 | c.2054C>A p.S685Y (on ENST00000541284 / NM_001190850.1; = p.S611Y on NM_013316.4) | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs959505788; called by muse, mutect2, varscan2
- CNTFR | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 170/356 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs776532201, COSV100667623; called by muse, varscan2
- CNTNAP5 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 97/214 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs752392550, COSV101443557; called by muse, mutect2, varscan2
- COG2 | c.380del p.K127Rfs*5 | Frame Shift Del (DEL) | VAF 44/140 reads (31%) | catalogued as rs1188081815, COSV100794718; called by mutect2, varscan2
- COL11A2 | c.2483G>A p.R828Q (on ENST00000341947 / NM_080680.3; = p.R721Q on NM_080679.2) | Missense Mutation (SNP) | VAF 229/463 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs765292733, COSV100553921; called by muse, mutect2, varscan2
- COL18A1 | c.5009G>A p.R1670H (on ENST00000359759 / NM_130444.3; = p.R1435H on NM_030582.4) | Missense Mutation (SNP) | VAF 241/460 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs757116735, COSV60589336; called by muse, mutect2, varscan2
- COL1A2 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 168/361 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1299614964; called by muse, mutect2, varscan2
- COL20A1 | c.3660del p.M1221Cfs*? | Frame Shift Del (DEL) | VAF 110/248 reads (44%) | catalogued as COSV100491399; called by mutect2, pindel, varscan2
- COPA | c.2498C>T p.A833V | Missense Mutation (SNP) | VAF 74/264 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs746722049; called by muse, mutect2, varscan2
- COQ6 | c.783G>A p.P261= | Splice Region (SNP) | VAF 236/449 reads (53%) | catalogued as rs199768730; called by muse, mutect2, varscan2
- CORIN | c.2747C>T p.P916L | Missense Mutation (SNP) | VAF 176/345 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs760929855; called by muse, mutect2, varscan2
- CPAMD8 | c.3153dup p.H1052Afs*30 (on ENST00000651564; = p.H1005Afs*30 on NM_015692.5) | Frame Shift Ins (INS) | VAF 138/328 reads (42%) | catalogued as rs750161916; called by mutect2, varscan2
- CPLANE1 | c.257C>T p.A86V (on ENST00000425232; = p.A158V on NM_023073.3) | Missense Mutation (SNP) | VAF 114/233 reads (49%) | SIFT tolerated (0.8); PolyPhen benign (0.012); catalogued as rs751087543; called by muse, mutect2, varscan2
- CPNE2 | c.812A>G p.Q271R | Missense Mutation (SNP) | VAF 95/215 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs761049290; called by muse, mutect2, varscan2
- CPSF3 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.457); catalogued as COSV53012335; called by muse, mutect2, varscan2
- CRACD | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 137/286 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.114); catalogued as COSV99950244; called by muse, mutect2, varscan2
- CRACD | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 121/224 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749775575; called by muse, mutect2, varscan2
- CRADD | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761865609, COSV60553386, COSV60554501; called by muse, mutect2
- CRB2 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 143/312 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753791463, COSV63504880; called by muse, mutect2, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 124/314 reads (39%) | catalogued as rs1378599948; called by mutect2, pindel, varscan2
- CREM | c.859C>T p.R287C (on ENST00000429130; = p.R242C on NM_181571.3) | Missense Mutation (SNP) | VAF 94/194 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs760612758, COSV59770260; called by muse, mutect2, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 50/102 reads (49%) | catalogued as rs769538822; called by mutect2, varscan2
- CSMD2 | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.407); catalogued as rs972030736, COSV53950724; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 215/295 reads (73%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CTAG2 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 161/349 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as rs782161068, COSV55994250; called by muse, mutect2, varscan2
- CTDP1 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1266242215, COSV50001844; called by muse, mutect2
- CTIF | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 144/315 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.939); catalogued as rs999388776, COSV56480317; called by muse, mutect2, varscan2
- CUBN | c.5083C>T p.R1695C | Missense Mutation (SNP) | VAF 203/415 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs770776726; called by muse, mutect2, varscan2
- CUX2 | c.2621G>A p.R874H | Missense Mutation (SNP) | VAF 117/227 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV55647884; called by muse, mutect2, varscan2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs772257590; called by mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 81/286 reads (28%) | catalogued as rs756254049; called by mutect2, pindel, varscan2
- CYP2C19 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 234/480 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64907386; called by muse, mutect2, varscan2
- CYP2F1 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 100/215 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as rs371341517; called by muse, mutect2, varscan2
- CYP4F22 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 294/601 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748463754; called by muse, mutect2, varscan2
- CYYR1 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs143400859; called by muse, mutect2, varscan2
- DAAM2 | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 73/137 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs749423164, COSV51302512; called by muse, mutect2, varscan2
- DAXX | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 212/453 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.223); catalogued as COSV56466160; called by muse, mutect2, varscan2
- DCAF15 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 104/232 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs778950385, COSV54330638; called by muse, mutect2, varscan2
- DCAF5 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 138/298 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs750163325; called by muse, mutect2, varscan2
- DCBLD2 | c.985A>C p.K329Q | Missense Mutation (SNP) | VAF 182/383 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV58788923; called by muse, mutect2, varscan2
- DCDC1 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs931421406, COSV60833505; called by muse, mutect2, varscan2
- DDX51 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs780739881, COSV57957056; called by muse, mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 28/65 reads (43%) | catalogued as rs553532837; called by mutect2, varscan2
- DGKH | c.2207C>T p.S736L | Missense Mutation (SNP) | VAF 128/288 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs868257718, COSV54927833; called by muse, varscan2
- DGKQ | c.1739C>A p.A580E | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV53278337; called by muse, mutect2, varscan2
- DHX37 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs376228891; called by muse, mutect2, varscan2
- DIO2 | c.56del p.F19Sfs*23 | Frame Shift Del (DEL) | VAF 85/215 reads (40%) | catalogued as rs148778534; called by mutect2, pindel, varscan2
- DIP2A | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1168353430, COSV100595272; called by muse, mutect2, varscan2
- DIRAS3 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 147/241 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63970685; called by muse, mutect2, varscan2
- DISP2 | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.308); catalogued as COSV99139933; called by muse, mutect2, varscan2
- DISP3 | c.3688G>A p.G1230S | Missense Mutation (SNP) | VAF 115/205 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs374923562, COSV53824728; called by muse, mutect2, varscan2
- DISP3 | c.3874G>A p.A1292T | Missense Mutation (SNP) | VAF 145/319 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53829192, COSV53830869; called by muse, mutect2, varscan2
- DKC1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 126/258 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs782121373; called by muse, mutect2, varscan2
- DNAAF3 | c.584G>A p.R195H (on ENST00000524407 / NM_001256715.2; = p.R242H on NM_178837.4) | Missense Mutation (SNP) | VAF 85/179 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs1205307808; called by muse, mutect2, varscan2
- DNAH1 | c.6940C>T p.R2314C | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776689300, COSV70227864; called by muse, mutect2
- DNAJC7 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as rs782177565; called by muse, mutect2, varscan2
- DNHD1 | c.797G>A p.S266N | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV54434867, COSV99600242; called by muse, mutect2, varscan2
- DNHD1 | c.2935C>T p.R979C | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs566226547, COSV54433194; called by muse, mutect2, varscan2
- DNM3 | c.2258C>T p.P753L (on ENST00000355305 / NM_001350206.2; = p.P747L on NM_015569.5) | Missense Mutation (SNP) | VAF 114/343 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs777632501, COSV62456380; called by muse, mutect2, varscan2
- DOCK1 | c.2251C>A p.R751S | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV99726406; called by muse, mutect2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 17/24 reads (71%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOK5 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 90/205 reads (44%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.553); catalogued as rs965183462, COSV52818039; called by muse, mutect2, varscan2
- DRAXIN | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 14/142 reads (10%) | catalogued as rs773581745; called by muse, mutect2
- DRC7 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 155/343 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.857); catalogued as rs768319912; called by muse, mutect2, varscan2
- DRICH1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 217/471 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.913); catalogued as rs775895089, COSV58503806; called by muse, mutect2, varscan2
- DRP2 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371570852, COSV100871779; called by muse, mutect2, varscan2
- DSC1 | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as rs777889677, COSV57145486, COSV57152642; called by muse, mutect2, varscan2
- DTX3 | c.433del p.L145Cfs*51 | Frame Shift Del (DEL) | VAF 21/173 reads (12%) | catalogued as rs758962538; called by mutect2, pindel, varscan2
- DUS1L | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 152/310 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as rs145224994; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 42/119 reads (35%) | catalogued as rs746928635; called by pindel, varscan2
- DYNC1H1 | c.2278G>A p.V760I | Missense Mutation (SNP) | VAF 214/445 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.444); catalogued as rs781320162; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EBF4 | c.1780C>T p.R594W (on ENST00000609451; = p.R590W on NM_001110514.1) | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as rs377714631; called by muse, mutect2, varscan2
- ECM2 | c.30dup p.L11Sfs*8 | Frame Shift Ins (INS) | VAF 64/139 reads (46%) | catalogued as rs752987091; called by mutect2, varscan2
- EFCAB7 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as rs775237667, COSV64314754; called by muse, mutect2, varscan2
- EFHC1 | c.1918G>C p.G640R | Missense Mutation (SNP) | VAF 78/155 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1006245677; called by muse, mutect2, varscan2
- EGFL6 | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs770186163; called by muse, mutect2, varscan2
- EGR2 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 66/263 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54347453; called by muse, mutect2, varscan2
- EHD1 | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 284/566 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); catalogued as rs757811551; called by muse, mutect2, varscan2
- EHD3 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs771567803, COSV59029851; called by muse, mutect2, varscan2
- EIF4EBP2 | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.596); catalogued as rs1392989013, COSV64667793; called by muse, mutect2, varscan2
- ELAVL2 | c.704A>G p.Q235R | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV56370644; called by mutect2, varscan2
- ELFN1 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 23/275 reads (8%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.446); catalogued as rs770244441, COSV70034717; called by muse, mutect2
- ELOVL1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 203/435 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs753516275; called by muse, mutect2, varscan2
- EMC8 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 118/242 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV53667789; called by muse, mutect2, varscan2
- EME1 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 99/236 reads (42%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.517); catalogued as rs781277541, COSV99869573; called by muse, mutect2, varscan2
- ENGASE | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 115/258 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs754563242, COSV56136421; called by muse, mutect2, varscan2
- ENO4 | c.623del p.K208Rfs*32 (on ENST00000622726; = p.K207Rfs*32 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 76/82 reads (93%) | catalogued as rs761717176; called by mutect2, varscan2
- EPHB6 | c.849dup p.R284Qfs*41 | Frame Shift Ins (INS) | VAF 51/135 reads (38%) | catalogued as rs145544148; called by mutect2, varscan2
- EPX | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 120/253 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs753502394; called by muse, mutect2, varscan2
- ERCC6 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 224/479 reads (47%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs774463252; called by muse, mutect2, varscan2
- ERG | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 67/116 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as rs144012510; called by muse, mutect2, varscan2
- ERVMER34-1 | c.899del p.L300Cfs*33 | Frame Shift Del (DEL) | VAF 157/310 reads (51%) | catalogued as rs779855268; called by mutect2, varscan2
- ESR1 | c.1678G>A p.V560M | Missense Mutation (SNP) | VAF 294/617 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs745984515, COSV99237340; called by muse, mutect2, varscan2
- EVI5 | c.1222dup p.M408Nfs*5 | Frame Shift Ins (INS) | VAF 42/82 reads (51%) | catalogued as rs760182064; called by mutect2, varscan2
- EXOC3L1 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs772773128, COSV52045258; called by muse, mutect2, varscan2
- EXOSC8 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757600036; called by muse, mutect2, varscan2
- EXPH5 | c.4832G>A p.S1611N | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.386); catalogued as rs933593785; called by muse, mutect2, varscan2
- EZH2 | c.1823G>A p.R608Q (on ENST00000460911 / NM_001203247.2; = p.R613Q on NM_004456.5) | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs561605379, COSV100236491; called by mutect2, varscan2
- F13A1 | c.869del p.P290Hfs*72 | Frame Shift Del (DEL) | VAF 85/242 reads (35%) | catalogued as CM103179, COSV53554649; called by pindel, varscan2
- FABP6 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 81/168 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs17856662, COSV67436666; called by muse, mutect2, varscan2
- FAH | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 166/365 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs755234891, COSV55720695; called by muse, mutect2, varscan2
- FAM131C | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs939398090; called by muse, mutect2, varscan2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 76/147 reads (52%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM161B | c.255del p.E86Sfs*35 (on ENST00000651776; = p.E23Sfs*35 on NM_152445.3) | Frame Shift Del (DEL) | VAF 42/130 reads (32%) | catalogued as rs775951198; called by mutect2, pindel, varscan2
- FAM166C | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 202/392 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as rs767810976, COSV99052108; called by muse, varscan2
- FAM189B | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 17/338 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs900723865; called by muse, mutect2
- FAM214A | c.3050G>A p.R1017Q | Missense Mutation (SNP) | VAF 104/210 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs1268904252; called by muse, mutect2, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 51/113 reads (45%) | catalogued as rs746881923; called by mutect2, pindel, varscan2
- FAM219A | c.492del p.K165Sfs*3 (on ENST00000445726; = p.K148Sfs*3 on NM_147202.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 25/58 reads (43%) | catalogued as rs760074479; called by mutect2, pindel, varscan2
- FAM220A | c.194T>C p.M65T | Missense Mutation (SNP) | VAF 187/390 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs551687469; called by muse, mutect2, varscan2
- FAM83C | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 243/466 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs375557298; called by muse, mutect2, varscan2
- FAM83D | c.1543del p.H515Tfs*6 | Frame Shift Del (DEL) | VAF 253/622 reads (41%) | catalogued as rs754952124; called by mutect2, pindel, varscan2
- FAM83H | c.2727del p.E910Sfs*64 | Frame Shift Del (DEL) | VAF 284/920 reads (31%) | catalogued as COSV100567936; called by mutect2, pindel, varscan2
- FASN | c.5116G>A p.A1706T | Missense Mutation (SNP) | VAF 253/523 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV60754793; called by muse, mutect2, varscan2
- FBH1 | c.2056G>A p.A686T (on ENST00000362091 / NM_178150.3; = p.A737T on NM_032807.4) | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.87); catalogued as rs1319822702, COSV62981687; called by muse, mutect2, varscan2
- FBN2 | c.5588G>A p.R1863Q | Missense Mutation (SNP) | VAF 239/496 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.083); catalogued as rs1447600676; called by muse, mutect2, varscan2
- FBXL4 | c.953T>G p.L318R | Missense Mutation (SNP) | VAF 137/316 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766177758; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXL7 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 139/308 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100309871; called by muse, mutect2, varscan2
- FBXO22 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs958919463, COSV57618114, COSV57619241; called by muse, mutect2, varscan2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 22/30 reads (73%) | catalogued as rs1288807478; called by mutect2, varscan2
- FDXACB1 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 151/339 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs191172184; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | catalogued as rs748969702; called by mutect2, varscan2
- FFAR2 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 131/293 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200165905, COSV55831656; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 5/53 reads (9%) | catalogued as rs777980924; called by mutect2, pindel
- FITM1 | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 148/304 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV52823528; called by muse, mutect2, varscan2
- FLCN | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 163/357 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs752006809, COSV53259578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLII | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 183/405 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs745739120, COSV58947560; called by muse, mutect2, varscan2
- FLNC | c.2561C>T p.A854V | Missense Mutation (SNP) | VAF 15/463 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs1263743573; called by muse, mutect2
- FLRT2 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 100/244 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766170020, COSV100420725, COSV58149961; called by muse, mutect2, varscan2
- FMNL3 | c.2269G>A p.V757I | Missense Mutation (SNP) | VAF 134/310 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs773190923, COSV53301582; called by muse, mutect2, varscan2
- FOXJ1 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1394240137; called by muse, mutect2, varscan2
- FOXN1 | c.1465dup p.Q489Pfs*40 | Frame Shift Ins (INS) | VAF 44/116 reads (38%) | catalogued as rs1169577591; called by mutect2, pindel, varscan2
- FREM2 | c.8056G>A p.V2686M | Missense Mutation (SNP) | VAF 154/311 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs144935150; called by muse, mutect2, varscan2
- FREM3 | c.5454del p.D1819Tfs*25 | Frame Shift Del (DEL) | VAF 96/247 reads (39%) | catalogued as rs1560848767; called by mutect2, pindel, varscan2
- FREM3 | c.5236G>A p.A1746T | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs1050229662; called by muse, mutect2, varscan2
- FSCN1 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 113/258 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs754863638, COSV61017595; called by muse, mutect2, varscan2
- FSD1L | c.319C>T p.R107C (on ENST00000481272 / NM_001145313.3; = p.R75C on NM_031919.5) | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.634); catalogued as rs200324817; called by muse, mutect2, varscan2
- FURIN | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 120/250 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1246114763; called by muse, mutect2, varscan2
- FZD5 | c.480dup p.R161Qfs*108 | Frame Shift Ins (INS) | VAF 67/193 reads (35%) | catalogued as rs1413162495; called by mutect2, pindel, varscan2
- GABBR1 | c.1721del p.P574Qfs*32 | Frame Shift Del (DEL) | VAF 56/153 reads (37%) | catalogued as rs777471402; called by mutect2, pindel, varscan2
- GABRG3 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 122/283 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs1181064418, COSV61509011, COSV61531239; called by muse, mutect2, varscan2
- GADD45B | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV53126504; called by muse, mutect2, varscan2
- GADL1 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 110/221 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.119); catalogued as rs1257298779; called by muse, mutect2, varscan2
- GAK | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs772535302; called by muse, mutect2, varscan2
- GALNT17 | c.1097del p.G366Afs*50 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | catalogued as COSV100351740; called by mutect2, pindel, varscan2
- GAS8 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 132/260 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs765671895; called by muse, mutect2, varscan2
- GBF1 | c.1258G>A p.D420N (on ENST00000369983 / NM_001377137.1; = p.D419N on NM_004193.3) | Missense Mutation (SNP) | VAF 190/388 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs41303829; called by muse, mutect2, varscan2
- GCN1 | c.3803G>A p.R1268Q | Missense Mutation (SNP) | VAF 90/211 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1341306715, COSV56109840; called by muse, mutect2, varscan2
- GCN1 | c.2849C>T p.A950V | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs575068347; called by muse, mutect2, varscan2
- GCNT2 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 112/249 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764632923; called by muse, mutect2, varscan2
- GDF10 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.102); catalogued as rs376019600; called by muse, mutect2
- GDF7 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 155/303 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV55347940; called by muse, mutect2, varscan2
- GDPD5 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 101/260 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs565726247; called by muse, mutect2, varscan2
- GEMIN4 | c.1831G>A p.V611I | Missense Mutation (SNP) | VAF 152/362 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.772); catalogued as rs368058625; called by muse, mutect2, varscan2
- GFPT2 | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 18/254 reads (7%) | catalogued as rs755563095; called by muse, mutect2
- GIGYF1 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs771986611, COSV51941211; called by muse, varscan2
- GIGYF1 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 96/183 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.037); catalogued as rs1220831821; called by muse, varscan2
- GIPC1 | c.149del p.P50Lfs*48 | Frame Shift Del (DEL) | VAF 144/304 reads (47%) | catalogued as rs771881138; called by mutect2, varscan2
- GJA1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 252/481 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as CM095018, COSV56997932; called by muse, mutect2, varscan2
- GLT1D1 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1056085473; called by muse, mutect2, varscan2
- GLUD1 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 143/321 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1050159; called by muse, mutect2, varscan2
- GLYCTK | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 79/158 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs547489088; called by muse, mutect2, varscan2
- GMPPA | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 92/201 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs752124820, COSV100354866; called by muse, mutect2, varscan2
- GNAS | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 302/647 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as COSV55690068; called by muse, mutect2, varscan2
- GNL3 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 143/285 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1316204392; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 450/1768 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as rs1242360337; called by muse, varscan2
- GORASP2 | c.1251del p.T418Lfs*74 | Frame Shift Del (DEL) | VAF 121/350 reads (35%) | catalogued as COSV52202002; called by pindel, varscan2
- GPAA1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 52/474 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372934708, COSV99049800; called by muse, mutect2, varscan2
- GPR143 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 123/275 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1309522047, COSV101102189; called by muse, mutect2, varscan2
- GPR26 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 160/338 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.865); catalogued as COSV52936362; called by muse, mutect2, varscan2
- GPR61 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 111/223 reads (50%) | catalogued as COSV68177448; called by muse, mutect2, varscan2
- GRB7 | c.276del p.L93Cfs*11 | Frame Shift Del (DEL) | VAF 11/98 reads (11%) | catalogued as COSV58447621; called by mutect2, pindel, varscan2
- GRIFIN | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 148/304 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs766790997; called by muse, mutect2, varscan2
- GRK1 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 324/667 reads (49%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.938); catalogued as rs372559555; called by muse, mutect2, varscan2
- GRM6 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51432798; called by muse, mutect2, varscan2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | catalogued as COSV58842099; called by mutect2, varscan2
- GSDME | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 212/485 reads (44%) | SIFT tolerated (0.8); PolyPhen benign (0.03); catalogued as rs139931428; called by muse, mutect2, varscan2
- H2BC4 | c.17A>G p.K6R | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs748963266, COSV58416857; called by muse, mutect2, varscan2
- H2BW2 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 104/242 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1482998729, COSV99685859, COSV99685922; called by muse, mutect2
- H3-4 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 145/490 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.155); catalogued as rs756810829; called by muse, mutect2, varscan2
- HCN1 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 311/668 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV57501369, COSV57539260; called by muse, mutect2, varscan2
- HDHD2 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200669234; called by muse, mutect2, varscan2
- HDHD2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as rs142900978, COSV56075290; called by muse, mutect2, varscan2
- HECTD4 | c.6626C>T p.A2209V | Missense Mutation (SNP) | VAF 84/173 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.767); catalogued as COSV66387705; called by muse, mutect2, varscan2
- HECTD4 | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 110/227 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs552220692; called by muse, mutect2, varscan2
- HELQ | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.521); catalogued as rs748050831, COSV55024306; called by muse, mutect2, varscan2
- HEYL | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 138/290 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs368236989; called by muse, mutect2, varscan2
- HHLA1 | c.532G>T p.V178L | Missense Mutation (SNP) | VAF 255/411 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs1001027644; called by muse, mutect2, varscan2
- HIC2 | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV101335591, COSV68041728; called by muse, mutect2
- HIP1 | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 123/291 reads (42%) | catalogued as rs1247000628, COSV100417796; called by muse, mutect2, varscan2
- HIP1 | c.176A>G p.H59R | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100417174; called by muse, mutect2, varscan2
- HMCN2 | c.9197C>T p.A3066V | Missense Mutation (SNP) | VAF 180/385 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs1052451359, COSV101508804; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 40/93 reads (43%) | catalogued as rs761272507; called by mutect2, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 48/136 reads (35%) | catalogued as rs755016625; called by mutect2, varscan2
- HOXC13 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 247/474 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54498075; called by muse, mutect2, varscan2
- HP | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs768960704; called by muse, mutect2, varscan2
- HSPG2 | c.4003G>A p.A1335T | Missense Mutation (SNP) | VAF 268/604 reads (44%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs532799636; called by muse, mutect2, varscan2
- HTR3C | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as rs138533542, COSV59175400; called by muse, mutect2, varscan2
- HTRA2 | c.346dup p.A116Gfs*22 | Frame Shift Ins (INS) | VAF 29/86 reads (34%) | catalogued as rs779457274; called by mutect2, varscan2
- IDH2 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 198/414 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51564478; called by muse, mutect2, varscan2
- IDO2 | c.302C>T p.A101V (on ENST00000389060; = p.A114V on NM_194294.2) | Missense Mutation (SNP) | VAF 131/253 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as rs1249765602, COSV100584888; called by muse, mutect2, varscan2
- IFI35 | c.17A>G p.D6G | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as rs977580584; called by muse, mutect2, varscan2
- IFRD2 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs782601507, COSV57115664; called by muse, mutect2, varscan2
- IFT140 | c.1726C>T p.R576W | Missense Mutation (SNP) | VAF 134/308 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs757678246; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 126/286 reads (44%) | catalogued as rs760021495; called by mutect2, varscan2
- IGLV3-1 | c.165G>T p.Q55H | Missense Mutation (SNP) | VAF 281/577 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs137930227; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as COSV56239630; called by muse, mutect2
- IL20RA | c.1271_1273del p.E424del | In Frame Del (DEL) | VAF 110/245 reads (45%) | catalogued as rs757830334; called by pindel, varscan2
- IL24 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as rs771354331; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 174/412 reads (42%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- IMPDH2 | c.1378C>A p.L460M | Missense Mutation (SNP) | VAF 120/286 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV58247209; called by muse, mutect2, varscan2
- INO80B | c.1035dup p.P346Afs*? | Frame Shift Ins (INS) | VAF 48/100 reads (48%) | catalogued as rs752165206; called by mutect2, varscan2
- INSL3 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 48/359 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs762412864; called by muse, varscan2
- INSL3 | c.148del p.R50Afs*77 | Frame Shift Del (DEL) | VAF 88/294 reads (30%) | catalogued as rs1187807999, COSV57952815; ClinVar: uncertain significance; called by pindel, varscan2
- INSRR | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 29/448 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.391); catalogued as COSV63872359; called by muse, mutect2
- INTS10 | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as rs201728325; called by muse, varscan2
- INTS14 | c.1288dup p.T430Nfs*6 (on ENST00000313182 / NM_001366360.2; = p.T351Nfs*6 on NM_001136043.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 48/154 reads (31%) | catalogued as rs781635472; called by pindel, varscan2
- IQSEC1 | c.2407C>T p.R803* | Nonsense Mutation (SNP) | VAF 173/388 reads (45%) | catalogued as rs1332327407; called by muse, mutect2, varscan2
- IRF9 | c.79G>T p.G27* | Nonsense Mutation (SNP) | VAF 147/335 reads (44%) | catalogued as COSV60703061; called by muse, mutect2, varscan2
- IRX4 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as COSV51473581; called by muse, mutect2, varscan2
- IRX5 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs755039206; called by muse, mutect2, varscan2
- ISL2 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV51959183; called by muse, mutect2, varscan2
- ITGA8 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1010582317, COSV65237294; called by muse, mutect2, varscan2
- ITGA9 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 297/653 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1160031026; called by muse, mutect2, varscan2
- ITGAV | c.2647C>T p.R883W | Missense Mutation (SNP) | VAF 108/242 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs751267868; called by muse, mutect2, varscan2
- ITGB3 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 213/443 reads (48%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); catalogued as rs760480847, COSV71383470; called by muse, mutect2, varscan2
- ITGB4 | c.2468G>A p.R823H | Missense Mutation (SNP) | VAF 154/354 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs536954831; called by muse, mutect2, varscan2
- ITIH2 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs377268702; called by muse, mutect2
- ITPR1 | c.4756C>T p.R1586C (on ENST00000354582; = p.R1571C on NM_002222.7) | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs373619512, COSV100231723; called by muse, mutect2, varscan2
- ITPR3 | c.2563_2565del p.E855del | In Frame Del (DEL) | VAF 51/145 reads (35%) | catalogued as rs754177801; called by pindel, varscan2
- JCAD | c.2927C>T p.T976M | Missense Mutation (SNP) | VAF 145/292 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs756349116; called by muse, mutect2, varscan2
- JMJD6 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 76/140 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0.254); catalogued as rs1163022715; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 228/509 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs760597072, COSV59826591; called by muse, mutect2, varscan2
- JPH2 | c.62del p.G21Efs*54 | Frame Shift Del (DEL) | VAF 107/292 reads (37%) | catalogued as rs1206579645; called by mutect2, pindel, varscan2
- JSRP1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.381); catalogued as COSV55555737; called by muse, mutect2, varscan2
- KCNAB3 | c.697del p.A233Lfs*16 | Frame Shift Del (DEL) | VAF 34/95 reads (36%) | catalogued as rs745672481; called by mutect2, pindel, varscan2
- KCNG1 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 322/664 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1022678362; called by muse, mutect2, varscan2
- KCNG3 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 82/242 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs564466098; called by muse, mutect2, varscan2
- KCNH5 | c.11del p.G4Afs*37 | Frame Shift Del (DEL) | VAF 87/243 reads (36%) | catalogued as COSV59765016; called by mutect2, pindel, varscan2
- KCNJ14 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs992971743; called by muse, varscan2
- KCNJ8 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 96/177 reads (54%) | catalogued as COSV53716291; called by muse, mutect2, varscan2
- KCNK4 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 11/251 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV100107779; called by muse, mutect2
- KCNN2 | c.559G>A p.V187M (on ENST00000264773; = p.V399M on NM_021614.4) | Missense Mutation (SNP) | VAF 92/175 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as COSV99299748; called by muse, mutect2, varscan2
- KCNQ2 | c.1466G>A p.R489H (on ENST00000359125 / NM_172107.4; = p.R461H on NM_004518.6) | Missense Mutation (SNP) | VAF 42/404 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs988208315; called by muse, mutect2, varscan2
- KCNS3 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 178/328 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as rs775574102, COSV58406156; called by muse, mutect2, varscan2
- KDM1B | c.1669C>T p.R557C (on ENST00000449850; = p.R325C on NM_153042.4) | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs1156728397; called by muse, mutect2, varscan2
- KDM2B | c.2815C>T p.R939W | Missense Mutation (SNP) | VAF 132/254 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as COSV100997401; called by muse, mutect2, varscan2
- KDM3B | c.3950del p.P1317Rfs*10 | Frame Shift Del (DEL) | VAF 127/272 reads (47%) | catalogued as rs1561792565; called by mutect2, varscan2
- KEL | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 28/496 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV62336452; called by muse, mutect2
- KHDRBS2 | c.668del p.P223Lfs*6 | Frame Shift Del (DEL) | VAF 62/157 reads (39%) | catalogued as COSV55452564, COSV99028884; called by mutect2, pindel, varscan2
- KHK | c.111G>A p.W37* | Nonsense Mutation (SNP) | VAF 189/427 reads (44%) | catalogued as COSV53157764; called by muse, mutect2, varscan2
- KIAA0100 | c.151del p.W51Gfs*77 | Frame Shift Del (DEL) | VAF 49/133 reads (37%) | catalogued as rs1339576763; called by mutect2, pindel, varscan2
- KIAA2012 | c.1564G>A p.V522M | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1338742487; called by muse, mutect2, varscan2
- KIAA2026 | c.2187del p.A730Qfs*26 | Frame Shift Del (DEL) | VAF 54/120 reads (45%) | catalogued as rs749990720; called by mutect2, varscan2
- KIF21B | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 138/216 reads (64%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs770974908, COSV59752730; called by muse, mutect2, varscan2
- KIF26A | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 372/715 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs376020927; called by muse, mutect2, varscan2
- KIF26B | c.2660del p.P887Qfs*35 | Frame Shift Del (DEL) | VAF 88/307 reads (29%) | catalogued as rs1208357637; called by mutect2, pindel, varscan2
- KIF7 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 107/228 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as rs1394292136; called by muse, mutect2, varscan2
- KLF13 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs748941501, COSV56147031; called by muse, mutect2, varscan2
- KLHDC8B | c.48del p.M17Cfs*59 | Frame Shift Del (DEL) | VAF 83/195 reads (43%) | catalogued as rs756907493; called by mutect2, pindel, varscan2
- KLHL26 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 115/417 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1297490717; called by muse, mutect2, varscan2
- KLHL30 | c.870del p.G291Afs*34 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | catalogued as rs1559275279; called by mutect2, pindel, varscan2
- KLK8 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as rs747062903, COSV51593277; called by muse, mutect2, varscan2
- KLKB1 | c.418dup p.R140Kfs*5 | Frame Shift Ins (INS) | VAF 187/264 reads (71%) | catalogued as rs755680952; called by mutect2, pindel, varscan2
- KMT2C | c.5716C>T p.R1906* | Nonsense Mutation (SNP) | VAF 78/181 reads (43%) | catalogued as rs763438739, COSV51279719, COSV51462477; called by muse, mutect2, varscan2
- KPTN | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 98/191 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as rs1425926253; called by muse, mutect2, varscan2
- KRT38 | c.977C>T p.T326M | Missense Mutation (SNP) | VAF 171/363 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs760012734; called by muse, mutect2, varscan2
- KSR2 | c.1606del p.L536Sfs*61 | Frame Shift Del (DEL) | VAF 15/146 reads (10%) | catalogued as rs770565486; called by mutect2, pindel, varscan2
- L1TD1 | c.1517A>G p.Q506R | Missense Mutation (SNP) | VAF 169/348 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1366393767; called by muse, mutect2, varscan2
- LAMA2 | c.4825C>A p.L1609M | Missense Mutation (SNP) | VAF 156/353 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV70350725; called by muse, mutect2, varscan2
- LAMA5 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 88/186 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53372673; called by muse, mutect2, varscan2
- LAMB1 | c.2915C>T p.S972L | Missense Mutation (SNP) | VAF 212/473 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs547247575, COSV55970311; called by muse, mutect2, varscan2
- LANCL3 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 136/326 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.193); catalogued as COSV101065413; called by muse, mutect2, varscan2
- LARP1 | c.906del p.T303Pfs*23 (on ENST00000518297 / NM_033551.3; = p.T226Pfs*23 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 98/205 reads (48%) | catalogued as rs769338468, COSV60425051; called by mutect2, varscan2
- LARP1 | c.2351G>A p.R784H (on ENST00000518297 / NM_033551.3; = p.R707H on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 263/578 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs766791311, COSV60429251; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 44/118 reads (37%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LCA5 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs542672738, COSV63971174; called by muse, mutect2, varscan2
- LINGO3 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 110/240 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs1343054102; called by muse, mutect2, varscan2
- LLGL2 | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 94/180 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs754867865; called by muse, mutect2, varscan2
- LMAN1 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 79/137 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs751738490, COSV51829099; called by muse, varscan2
- LPP | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs748763447; called by muse, mutect2, varscan2
- LRCH3 | c.1962_1964del p.E655del | In Frame Del (DEL) | VAF 36/118 reads (31%) | catalogued as rs759920668; called by pindel, varscan2
- LRFN1 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.679); catalogued as rs1166129592; called by muse, mutect2, varscan2
- LRFN1 | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.362); catalogued as COSV50451647; called by muse, mutect2, varscan2
- LRP1 | c.13553G>A p.R4518H | Missense Mutation (SNP) | VAF 157/340 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs751094440; called by muse, mutect2, varscan2
- LRPPRC | c.62C>G p.P21R | Missense Mutation (SNP) | VAF 87/173 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.754); catalogued as rs746496250; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 47/110 reads (43%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC41 | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 72/542 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs377701856; called by muse, mutect2, varscan2
- LRRK1 | c.4975C>T p.R1659W | Missense Mutation (SNP) | VAF 171/319 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1015630432, COSV52608388; called by muse, mutect2, varscan2
- LRRTM1 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 85/164 reads (52%) | SIFT tolerated (0.81); PolyPhen benign (0.009); catalogued as COSV54448413; called by muse, varscan2
- LSM14B | c.257A>G p.Q86R | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as rs1277110925; called by muse, mutect2, varscan2
- LTBP1 | c.231del p.V79Sfs*143 | Frame Shift Del (DEL) | VAF 33/73 reads (45%) | catalogued as rs1215027021; called by mutect2, pindel, varscan2
- LTBP3 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 257/507 reads (51%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.959); catalogued as rs1161239982; called by muse, mutect2, varscan2
- LYPD2 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 58/672 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63649678; called by muse, mutect2
- LYST | c.5152C>T p.R1718* | Nonsense Mutation (SNP) | VAF 77/195 reads (39%) | catalogued as rs1412672912, COSV67713807; called by muse, mutect2, varscan2
- MAB21L1 | c.734del p.G245Afs*13 | Frame Shift Del (DEL) | VAF 89/225 reads (40%) | catalogued as rs1489102829, COSV100076702; called by mutect2, pindel, varscan2
- MAGEB17 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1388945346; called by muse, mutect2, varscan2
- MAGED2 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 87/177 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as rs867098630, COSV54497627; called by muse, mutect2, varscan2
- MAGEE1 | c.1045G>A p.G349S | Missense Mutation (SNP) | VAF 215/472 reads (46%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as rs782712878; called by muse, mutect2, varscan2
- MAGEE2 | c.133del p.Q45Sfs*27 | Frame Shift Del (DEL) | VAF 33/78 reads (42%) | catalogued as rs1159257962; called by mutect2, pindel, varscan2
- MAGEH1 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 145/316 reads (46%) | catalogued as COSV61679082; called by muse, mutect2, varscan2
- MAGI2 | c.2453G>A p.R818H | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs753587569; called by muse, varscan2
- MAMDC2 | c.1842_1844del p.R616del | In Frame Del (DEL) | VAF 58/137 reads (42%) | catalogued as rs1261530697; called by pindel, varscan2
- MAML1 | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 200/439 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs760412182; called by muse, mutect2, varscan2
- MAML2 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 200/382 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101594066; called by muse, mutect2, varscan2
- MAP1A | c.6193del p.R2065Vfs*5 | Frame Shift Del (DEL) | VAF 79/201 reads (39%) | catalogued as COSV55811343; called by mutect2, pindel, varscan2
- MAP4K1 | c.2215G>T p.V739F | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.9); catalogued as COSV101204137; called by muse, mutect2, varscan2
- MAPK4 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs767125390, COSV101245429; called by muse, mutect2, varscan2
- MARCO | c.114G>T p.R38S | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV59055942; called by muse, mutect2, varscan2
- MCF2L | c.487G>A p.V163I (on ENST00000375608; = p.V131I on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.942); catalogued as rs763446044, COSV65052183; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 32/66 reads (48%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCTP1 | c.1592_1594del p.G531del | In Frame Del (DEL) | VAF 110/324 reads (34%) | catalogued as rs749032818; called by pindel, varscan2
- MDFI | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 118/254 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.144); catalogued as COSV100025599, COSV57822239; called by muse, mutect2, varscan2
- MDGA2 | c.1961C>T p.T654M (on ENST00000399232 / NM_001113498.2; = p.T356M on NM_182830.4) | Missense Mutation (SNP) | VAF 197/374 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs758142772, COSV62081973; called by muse, mutect2, varscan2
- MED15 | c.1357del p.Q453Sfs*41 (on ENST00000263205 / NM_001003891.3; = p.Q413Sfs*41 on NM_015889.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 92/183 reads (50%) | catalogued as COSV99487865; called by mutect2, varscan2
- MED24 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs926133816; called by muse, mutect2
- MEGF6 | c.4318del p.A1440Hfs*78 | Frame Shift Del (DEL) | VAF 150/353 reads (42%) | catalogued as rs759225724, COSV53895347; called by mutect2, varscan2
- MEGF8 | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.237); catalogued as COSV52083190; called by muse, mutect2, varscan2
- MEX3D | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 152/281 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1163526597, COSV66312420; called by muse, mutect2, varscan2
- MEX3D | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 224/475 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs771190527, COSV66311958; called by muse, mutect2, varscan2
- MFSD10 | c.745del p.L249Wfs*29 | Frame Shift Del (DEL) | VAF 108/298 reads (36%) | catalogued as COSV99296832; called by mutect2, pindel, varscan2
- MGAT4B | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 113/231 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs748599210, COSV99482053; called by muse, mutect2, varscan2
- MICOS13 | c.150del p.A51Pfs*39 | Frame Shift Del (DEL) | VAF 70/166 reads (42%) | catalogued as rs751944867; called by mutect2, varscan2
- MIDEAS | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs751958957; called by muse, varscan2
- MIGA1 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 123/231 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs772067225, COSV66223452; called by muse, mutect2, varscan2
- MLF1 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 68/128 reads (53%) | catalogued as rs141212572; called by muse, varscan2
- MLLT1 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.523); catalogued as rs748081218, COSV99397844; called by muse, varscan2
- MLXIPL | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 216/442 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.197); catalogued as rs782092916, COSV57668767; called by muse, varscan2
- MLXIPL | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 227/497 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs782150923; called by muse, mutect2, varscan2
- MMD2 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 126/268 reads (47%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.028); catalogued as rs948008887, COSV68660649; called by muse, mutect2, varscan2
- MMP21 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 108/204 reads (53%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.903); catalogued as rs372562000; called by muse, mutect2, varscan2
- MMP8 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 116/252 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs563802778; called by muse, varscan2
- MN1 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1242456786; called by muse, varscan2
- MON2 | c.3943G>A p.A1315T | Missense Mutation (SNP) | VAF 98/205 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0.046); catalogued as rs1003008908; called by muse, mutect2, varscan2
- MPP6 | c.917del p.K306Rfs*4 | Frame Shift Del (DEL) | VAF 36/78 reads (46%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MRAP | c.107-5C>T | Splice Region (SNP) | VAF 226/469 reads (48%) | catalogued as rs373512270; called by muse, mutect2, varscan2
- MRPS16 | c.44del p.G15Afs*3 | Frame Shift Del (DEL) | VAF 87/346 reads (25%) | catalogued as COSV60284473; called by mutect2, pindel, varscan2
- MSRB1 | c.188G>T p.R63I | Missense Mutation (SNP) | VAF 195/447 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as rs770241137, COSV99238062; called by muse, mutect2, varscan2
- MST1 | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs750408728, COSV56533896; called by muse, mutect2
- MSX1 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 126/241 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs902284125, COSV66947773; called by muse, mutect2, varscan2
- MTCL1 | c.4714del p.A1572Hfs*28 (on ENST00000306329 / NM_001378206.1; = p.A1253Hfs*28 on NM_015210.4) | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | catalogued as rs1209504789; called by mutect2, pindel, varscan2
- MTHFSD | c.728G>A p.R243H (on ENST00000360900 / NM_001159377.2; = p.R242H on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs755482028; called by muse, varscan2
- MTMR3 | c.2349del p.R784Gfs*15 | Frame Shift Del (DEL) | VAF 174/416 reads (42%) | catalogued as COSV100070564; called by mutect2, varscan2
- MTUS2 | c.2518G>A p.G840R | Missense Mutation (SNP) | VAF 156/323 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200465559, COSV99079522; called by muse, mutect2, varscan2
- MUC16 | c.29203C>A p.L9735I | Missense Mutation (SNP) | VAF 137/248 reads (55%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.263); catalogued as rs755909314; called by muse, mutect2, varscan2
- MUC5B | c.5825C>T p.T1942M | Missense Mutation (SNP) | VAF 359/738 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as rs752678107, COSV71594918; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 114/323 reads (35%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYBPHL | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 85/207 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as rs199935853; called by muse, mutect2, varscan2
- MYH10 | c.5536C>T p.R1846C | Missense Mutation (SNP) | VAF 85/204 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs763285249, COSV99345450; called by muse, mutect2, varscan2
- MYH2 | c.3394C>T p.R1132W | Missense Mutation (SNP) | VAF 298/599 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs745807547, COSV55431734; called by muse, mutect2, varscan2
- MYH9 | c.3249G>T p.E1083D | Missense Mutation (SNP) | VAF 98/186 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV53387066; called by muse, mutect2, varscan2
- MYO10 | c.4636C>T p.P1546S | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs368821991; called by muse, mutect2, varscan2
- MYO15A | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 162/306 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs757868524; called by muse, mutect2, varscan2
- MYO18A | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV104416421; called by muse, mutect2, varscan2
- MYO19 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557418507; called by muse, mutect2, varscan2
- MYOCD | c.1867G>A p.V623I | Missense Mutation (SNP) | VAF 84/162 reads (52%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV58515032; called by muse, varscan2
- MYORG | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 203/377 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1339571925; called by muse, mutect2, varscan2
- MYOZ3 | c.412del p.A138Pfs*10 | Frame Shift Del (DEL) | VAF 70/187 reads (37%) | catalogued as COSV99770842; called by mutect2, pindel, varscan2
- MYRFL | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs1350428845; called by muse, mutect2, varscan2
- MYSM1 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747437450, COSV101284065; called by muse, mutect2, varscan2
- MYT1L | c.382del p.D128Tfs*46 | Frame Shift Del (DEL) | VAF 110/290 reads (38%) | catalogued as COSV67730728; called by mutect2, pindel, varscan2
- NAALADL2 | c.1586G>T p.S529I | Missense Mutation (SNP) | VAF 121/240 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV101380516; called by muse, mutect2, varscan2
- NBEA | c.3953G>A p.R1318H | Missense Mutation (SNP) | VAF 144/304 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59762766; called by muse, mutect2, varscan2
- NBEAL1 | c.1869dup p.T624Yfs*8 | Frame Shift Ins (INS) | VAF 26/70 reads (37%) | catalogued as rs1559372339; called by mutect2, varscan2
- NBPF11 | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 249/820 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.913); catalogued as rs1221652597; called by muse, mutect2, varscan2
- NCKAP1 | c.424A>C p.T142P | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV62939711; called by muse, varscan2
- NCKAP1L | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 94/192 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756906173, COSV53204504, COSV53210746; called by muse, mutect2, varscan2
- NDRG2 | c.467C>T p.A156V (on ENST00000298687 / NM_001354570.1; = p.A142V on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 169/378 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as rs1216275980; called by muse, mutect2, varscan2
- NDST2 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as rs1249833803, COSV100013765, COSV55212916; called by muse, mutect2, varscan2
- NDUFS8 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 237/498 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.646); catalogued as rs1282276522; called by muse, mutect2, varscan2
- NDUFV1 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 182/359 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs759807863; called by muse, mutect2, varscan2
- NEB | c.13756C>T p.R4586C | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs374606967; ClinVar: uncertain significance; called by muse, varscan2
- NECAB3 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756805849; called by muse, mutect2, varscan2
- NECTIN4 | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 55/717 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1478255615, COSV63513046; called by muse, mutect2
- NEDD4 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV100163310; called by muse, mutect2, varscan2
- NEURL1 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 165/326 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201516316; called by muse, mutect2, varscan2
- NFASC | c.3146C>T p.T1049M | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.833); catalogued as rs370138600; called by muse, mutect2
- NFATC2 | c.419del p.P140Rfs*28 | Frame Shift Del (DEL) | VAF 105/253 reads (42%) | catalogued as COSV101044898; called by mutect2, pindel, varscan2
- NFIA | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 105/196 reads (54%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.979); catalogued as rs751696907, COSV64533596; called by muse, mutect2, varscan2
- NHLRC1 | c.612del p.F204Lfs*28 | Frame Shift Del (DEL) | VAF 166/455 reads (36%) | catalogued as rs1171412241, CD054388; called by mutect2, pindel, varscan2
- NIN | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 117/230 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1348032914, COSV55381045; called by muse, mutect2, varscan2
- NKTR | c.2297del p.N766Ifs*30 | Frame Shift Del (DEL) | VAF 92/206 reads (45%) | catalogued as rs767007251; called by mutect2, varscan2
- NKX2-6 | c.30del p.F11Sfs*34 | Frame Shift Del (DEL) | VAF 59/154 reads (38%) | catalogued as COSV100273957; called by mutect2, pindel, varscan2
- NLE1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs745418741, COSV62604060; called by muse, mutect2, varscan2
- NLRP14 | c.11C>G p.S4* | Nonsense Mutation (SNP) | VAF 96/251 reads (38%) | catalogued as COSV55069500; called by muse, varscan2
- NLRP2 | c.1346C>T p.T449M | Missense Mutation (SNP) | VAF 197/447 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as rs144271525; called by muse, mutect2, varscan2
- NLRP6 | c.866dup p.E291Rfs*75 | Frame Shift Ins (INS) | VAF 12/106 reads (11%) | catalogued as rs771837860; called by mutect2, varscan2
- NOL4 | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 48/98 reads (49%) | catalogued as COSV52347042; called by muse, mutect2, varscan2
- NOL4L | c.396del p.Y133Tfs*20 | Frame Shift Del (DEL) | VAF 80/161 reads (50%) | catalogued as rs751187638; called by mutect2, varscan2
- NOL8 | c.418-8del | Splice Region (DEL) | VAF 57/128 reads (45%) | catalogued as rs756440973; called by mutect2, varscan2
- NPHP1 | c.859A>G p.N287D | Missense Mutation (SNP) | VAF 162/330 reads (49%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as CM066933; called by muse, varscan2
- NPHP4 | c.2866G>A p.A956T | Missense Mutation (SNP) | VAF 146/273 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs369624442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPIPB15 | c.1283del p.K428Rfs*? | Frame Shift Del (DEL) | VAF 158/868 reads (18%) | catalogued as rs1567419461; called by pindel, varscan2
- NPIPB5 | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 443/3364 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.978); catalogued as rs1443203359, COSV69996000; called by muse, varscan2
- NPM2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 116/231 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV57075073; called by muse, mutect2, varscan2
- NPNT | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs899234227, COSV59755820; called by muse, mutect2, varscan2
- NPRL3 | c.1162-5C>T | Splice Region (SNP) | VAF 95/194 reads (49%) | catalogued as rs768868339; called by muse, mutect2, varscan2
- NR1H2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.476); catalogued as rs1349280396; called by muse, mutect2, varscan2
- NR3C1 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as rs748311337; called by muse, mutect2, varscan2
- NRN1L | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 331/642 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs745469040; called by muse, mutect2, varscan2
- NSG1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 114/272 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs758849842, COSV60373572; called by muse, mutect2, varscan2
- NSMF | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 284/556 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as rs1038133430, COSV52993979; called by muse, mutect2, varscan2
- NSRP1 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs572953048, COSV55936160; called by muse, mutect2, varscan2
- NSUN2 | c.1797_1798del p.A600Ffs*16 | Frame Shift Del (DEL) | VAF 91/287 reads (32%) | catalogued as rs1394056446; called by pindel, varscan2
- NTN3 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as rs765907721; called by muse, mutect2, varscan2
- NUAK2 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780926337, COSV100904057, COSV100904097; called by muse, mutect2, varscan2
- NUDT18 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1270855846; called by muse, mutect2, varscan2
- NUDT3 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101466190; called by muse, mutect2, varscan2
- NUDT5 | c.266del p.G89Afs*4 | Frame Shift Del (DEL) | VAF 92/201 reads (46%) | catalogued as rs1564424334; called by mutect2, varscan2
- NUP155 | c.3391A>G p.I1131V (on ENST00000231498 / NM_153485.3; = p.I1072V on NM_004298.4) | Missense Mutation (SNP) | VAF 11/294 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as rs911463161; called by muse, mutect2
- NUTM2D | c.767G>A p.S256N | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1318081966; called by mutect2, varscan2
- NUTM2E | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.324); catalogued as rs1233320439; called by mutect2, varscan2
- NUTM2F | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 149/510 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs767026006; called by muse, varscan2
- NXN | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 154/439 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs200704586; called by muse, mutect2
- NXPH4 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 234/533 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs865982196; called by muse, mutect2, varscan2
- OBSCN | c.5648G>A p.R1883H | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.98); catalogued as rs765855953, COSV52819912; called by muse, mutect2, varscan2
- OBSCN | c.5728G>A p.A1910T | Missense Mutation (SNP) | VAF 171/255 reads (67%) | SIFT tolerated (0.25); PolyPhen benign (0.095); catalogued as rs574126820; called by muse, mutect2, varscan2
- OBSCN | c.6589C>T p.R2197C | Missense Mutation (SNP) | VAF 152/260 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs868640041, COSV99472215; called by muse, mutect2, varscan2
- OBSCN | c.9869C>T p.T3290M | Missense Mutation (SNP) | VAF 54/313 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.968); catalogued as rs201902729; called by muse, mutect2, varscan2
- OPN4 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 80/149 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs775728827, COSV54118171; called by muse, mutect2
- OR10G7 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 125/258 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs779903828, COSV57869277; called by muse, mutect2, varscan2
- OR1J4 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 112/235 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.178); catalogued as rs759858630; called by muse, mutect2, varscan2
- OR2M3 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 268/424 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV101513415; called by muse, mutect2, varscan2
- OR4C15 | c.328T>C p.S110P (on ENST00000314644; = p.S56P on NM_001001920.2) | Missense Mutation (SNP) | VAF 152/295 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1250653132; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 352/369 reads (95%) | catalogued as rs755413956; called by mutect2, varscan2
- OR52R1 | c.663del p.Y221* | Frame Shift Del (DEL) | VAF 106/280 reads (38%) | catalogued as COSV61889447; called by mutect2, pindel, varscan2
- OR6P1 | c.96del p.F32Lfs*6 | Frame Shift Del (DEL) | VAF 91/286 reads (32%) | catalogued as rs201077183; called by mutect2, varscan2
- OR8D1 | c.853C>A p.L285M | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.988); catalogued as COSV63442776; called by muse, mutect2, varscan2
- OSBP2 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 142/375 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV60241264; called by muse, mutect2, varscan2
- OTOS | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs370264573; called by muse, mutect2, varscan2
- OXER1 | c.231del p.S78Pfs*64 | Frame Shift Del (DEL) | VAF 132/321 reads (41%) | catalogued as rs753912794; called by mutect2, pindel, varscan2
- OXNAD1 | c.83T>C p.L28S | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99551013; called by muse, mutect2, varscan2
- P3H2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs865964864; called by muse, mutect2, varscan2
- PAFAH2 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100959210; called by muse, mutect2, varscan2
- PARD3B | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs777246153; called by muse, mutect2, varscan2
- PARD6G | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 199/394 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62061070; called by muse, mutect2, varscan2
- PARP10 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 18/522 reads (3%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs201355422; called by muse, mutect2
- PARP14 | c.3599C>T p.P1200L | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs745695997; called by muse, mutect2, varscan2
- PATL1 | c.478dup p.Q160Pfs*6 | Frame Shift Ins (INS) | VAF 38/92 reads (41%) | catalogued as rs757903860; called by mutect2, varscan2
- PAXX | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 31/390 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1294640289; called by muse, mutect2
- PCDH15 | c.4049G>A p.R1350H | Missense Mutation (SNP) | VAF 166/325 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs752356781, COSV57265804, COSV57366433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH17 | c.2512G>A p.G838R | Missense Mutation (SNP) | VAF 186/393 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs1485429803; called by muse, mutect2, varscan2
- PCDH7 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 128/235 reads (54%) | catalogued as COSV62336392; called by muse, mutect2, varscan2
- PCDHA1 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 78/137 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs149577981, COSV65374522; called by muse, mutect2, varscan2
- PCDHA12 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 442/882 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); catalogued as rs1554169178, COSV100248065; called by muse, mutect2, varscan2
- PCDHA3 | c.596dup p.N199Kfs*9 | Frame Shift Ins (INS) | VAF 109/225 reads (48%) | catalogued as rs782411180; called by mutect2, varscan2
- PCDHB11 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 150/326 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554285419, COSV61312176; called by muse, mutect2, varscan2
- PCDHB2 | c.2140C>T p.R714W | Missense Mutation (SNP) | VAF 34/551 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.22); catalogued as rs1554271679, COSV50564354; called by muse, mutect2
- PCDHB5 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 374/806 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); catalogued as rs140704539; called by muse, mutect2, varscan2
- PCDHGB5 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 179/392 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs774561101, COSV53930506; called by muse, mutect2, varscan2
- PCDHGC4 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 198/381 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs769661146; called by muse, mutect2, varscan2
- PCIF1 | c.1796T>C p.M599T | Missense Mutation (SNP) | VAF 53/332 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs757074440; called by muse, mutect2, varscan2
- PCNT | c.3469G>A p.A1157T | Missense Mutation (SNP) | VAF 208/406 reads (51%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.837); catalogued as rs778900170, COSV64025671; called by muse, mutect2, varscan2
- PCSK6 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 97/200 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754908777; called by muse, mutect2, varscan2
- PDE4DIP | c.4138C>T p.R1380W | Missense Mutation (SNP) | VAF 142/766 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371331495; called by muse, mutect2, varscan2
- PDILT | c.680del p.K227Rfs*5 | Frame Shift Del (DEL) | VAF 34/80 reads (43%) | catalogued as rs745333926; called by mutect2, pindel, varscan2
- PDZD2 | c.6733C>T p.R2245C | Missense Mutation (SNP) | VAF 86/181 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs768642055, COSV56869983; called by muse, mutect2, varscan2
- PEG3 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 104/297 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs146466276; called by muse, mutect2, varscan2
- PER2 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 35/341 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1156426847, COSV99612613; called by muse, mutect2, varscan2
- PEX10 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 232/476 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs756537855, COSV99992257; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PEX13 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 82/186 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs766710343; called by muse, mutect2, varscan2
- PEX5L | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV55844949, COSV55860300; called by muse, mutect2, varscan2
- PFKP | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as rs1280636156; called by muse, mutect2, varscan2
- PGC | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 95/203 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs1187092869, COSV57823435; called by muse, mutect2, varscan2
- PGM5 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782325316, COSV67168284; called by muse, varscan2
- PHEX | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 197/493 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.462); catalogued as rs768400503, COSV101039549, COSV65078293; called by muse, mutect2, varscan2
- PHKA2 | c.3391G>C p.V1131L | Missense Mutation (SNP) | VAF 204/388 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV66056776; called by muse, mutect2, varscan2
- PHLPP1 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs539746714; called by muse, mutect2, varscan2
- PHLPP1 | c.3251G>A p.R1084H | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); catalogued as rs780394677, COSV53034405, COSV99408908; called by muse, mutect2, varscan2
- PHLPP2 | c.3403_3405del p.S1135del | In Frame Del (DEL) | VAF 138/336 reads (41%) | catalogued as rs747144814; called by pindel, varscan2
- PHLPP2 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 92/182 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1394778309, COSV62424175; called by muse, mutect2, varscan2
- PHRF1 | c.2009C>T p.A670V (on ENST00000264555 / NM_001286581.2; = p.A669V on NM_020901.4) | Missense Mutation (SNP) | VAF 141/269 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs778725659; called by muse, mutect2, varscan2
- PIAS4 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 95/199 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV99518808; called by muse, mutect2, varscan2
- PIGN | c.2577-5del | Splice Region (DEL) | VAF 36/66 reads (55%) | catalogued as rs138671843; ClinVar: benign / likely benign; called by mutect2, varscan2
- PIK3C2B | c.3727G>A p.V1243I | Missense Mutation (SNP) | VAF 133/376 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100915964; called by muse, mutect2, varscan2
- PIWIL3 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 118/267 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV59994393; called by muse, mutect2, varscan2
- PKD2 | c.2902G>A p.V968I | Missense Mutation (SNP) | VAF 115/300 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs549787080, COSV52936241, COSV52941197; called by muse, mutect2, varscan2
- PKDREJ | c.3364G>T p.G1122C | Missense Mutation (SNP) | VAF 137/257 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53548795; called by muse, mutect2, varscan2
- PKM | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 266/606 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs751885485, COSV58790471; called by muse, mutect2, varscan2
- PLAAT1 | c.389G>A p.R130H (on ENST00000650797; = p.R25H on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs150318874; called by muse, mutect2, varscan2
- PLEKHA8 | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 126/314 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs950425344, COSV99321287; called by muse, mutect2, varscan2
- PLEKHG4 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 149/288 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.191); catalogued as rs766255385; called by muse, mutect2, varscan2
- PLEKHM2 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 195/372 reads (52%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs1331611746; called by muse, mutect2, varscan2
- PLPP7 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 163/350 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs776448456; called by muse, mutect2, varscan2
- PLS3 | c.396G>C p.W132C | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99171705; called by muse, mutect2, varscan2
- PLXDC1 | c.593-9_593-7del | Splice Region (DEL) | VAF 84/226 reads (37%) | catalogued as rs755630405; called by pindel, varscan2
- PLXNA3 | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 89/192 reads (46%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.487); catalogued as COSV100860093; called by muse, mutect2, varscan2
- PLXNB1 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 173/346 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as rs760134829, COSV56487196; called by muse, mutect2, varscan2
- PNCK | c.633dup p.F212Lfs*8 (on ENST00000340888 / NM_001366975.1; = p.F295Lfs*8 on NM_001039582.3) | Frame Shift Ins (INS) | VAF 96/236 reads (41%) | catalogued as rs781891121; called by mutect2, varscan2
- PNMA8B | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 152/262 reads (58%) | SIFT tolerated (0.46); PolyPhen benign (0.024); catalogued as rs1401680037; called by muse, mutect2, varscan2
- PNPLA5 | c.693del p.S232Afs*4 | Frame Shift Del (DEL) | VAF 15/123 reads (12%) | catalogued as rs1218927828; called by mutect2, pindel
- POLR1A | c.4138G>A p.A1380T | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as rs546896040, COSV55701073; called by muse, mutect2, varscan2
- POLR1D | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 152/323 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1014369151, CM108857, COSV57256177; called by muse, mutect2, varscan2
- POLRMT | c.2766C>T p.D922= | Splice Region (SNP) | VAF 96/181 reads (53%) | catalogued as rs757311750; called by muse, mutect2, varscan2
- POSTN | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 95/185 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs771376752, COSV65712815; called by muse, mutect2, varscan2
- POU3F3 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs1207426311; called by muse, varscan2
- PPFIA2 | c.3397G>A p.G1133S | Missense Mutation (SNP) | VAF 112/283 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470742734, COSV61033523; called by muse, varscan2
- PPP1R14A | c.87del p.L30Cfs*54 | Frame Shift Del (DEL) | VAF 102/274 reads (37%) | catalogued as rs751874633; called by mutect2, pindel, varscan2
- PPP1R3C | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 97/175 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1415699605, COSV53289312; called by muse, mutect2, varscan2
- PPP1R3D | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.245); catalogued as rs746541345; called by muse, varscan2
- PPP1R3G | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 222/448 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.594); catalogued as COSV68161106; called by muse, mutect2, varscan2
- PPP2R5D | c.1261C>A p.R421S | Missense Mutation (SNP) | VAF 104/225 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs934509389; called by muse, mutect2, varscan2
- PPRC1 | c.3185C>T p.A1062V | Missense Mutation (SNP) | VAF 152/313 reads (49%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as rs1171066198; called by muse, mutect2, varscan2
- PRDM10 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as rs141679521; called by muse, mutect2, varscan2
- PRDM16 | c.1862C>T p.T621M | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs201912252; called by muse, mutect2, varscan2
- PRDM6 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 100/247 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as rs1257049339; called by muse, mutect2, varscan2
- PRKACA | c.470A>G p.Y157C | Missense Mutation (SNP) | VAF 113/235 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100431772; called by muse, mutect2, varscan2
- PRKCG | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 103/203 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs758442836; called by muse, mutect2, varscan2
- PRKCSH | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 36/536 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs369957270; called by muse, mutect2
- PRLR | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs781305716, COSV99184419; called by muse, mutect2, varscan2
- PRMT8 | c.38G>T p.R13M | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as COSV66890556, COSV66893301; called by muse, mutect2
- PROS1 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 97/206 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD951837; called by muse, mutect2, varscan2
- PRPF40A | c.2483G>A p.R828Q | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV68359595; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 148/162 reads (91%) | catalogued as rs753236928; called by mutect2, varscan2
- PRR35 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs751729638; called by muse, mutect2, varscan2
- PRSS56 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 126/225 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs1227274904; called by muse, mutect2, varscan2
- PSAP | c.556del p.R186Afs*20 | Frame Shift Del (DEL) | VAF 97/248 reads (39%) | catalogued as COSV67551246; called by mutect2, pindel, varscan2
- PSD3 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 163/306 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.691); catalogued as rs926362251; called by muse, mutect2, varscan2
- PSG6 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 163/356 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs769630585; called by muse, mutect2, varscan2
- PSMD2 | c.2419C>T p.R807* | Nonsense Mutation (SNP) | VAF 95/214 reads (44%) | catalogued as rs1489238012; called by muse, mutect2, varscan2
- PSME1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 166/343 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs146188494; called by muse, varscan2
- PTPRJ | c.2024C>T p.T675M | Missense Mutation (SNP) | VAF 144/266 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs778048790, COSV69253016; called by muse, mutect2, varscan2
- PTPRS | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53610456; called by muse, mutect2, varscan2
- PTPRU | c.1915C>T p.R639W | Missense Mutation (SNP) | VAF 180/354 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1380386412; called by muse, mutect2, varscan2
- PWP1 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs538198996, COSV69832378, COSV69832976; called by muse, mutect2, varscan2
- PWWP3B | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1569368779, COSV100531673; called by muse, mutect2, varscan2
- PXDN | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as rs749632473; called by muse, mutect2, varscan2
- PXDNL | c.2399C>T p.T800M | Missense Mutation (SNP) | VAF 74/134 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62481105; called by muse, mutect2, varscan2
- PXN | c.1591C>T p.R531C (on ENST00000228307 / NM_001080855.3; = p.R497C on NM_002859.4) | Missense Mutation (SNP) | VAF 196/386 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1325851694; called by muse, mutect2, varscan2
- PYDC1 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 126/258 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs377601641; called by muse, mutect2, varscan2
- PYHIN1 | c.423dup p.P142Tfs*3 | Frame Shift Ins (INS) | VAF 28/86 reads (33%) | catalogued as rs758393003; called by mutect2, varscan2
- PYROXD2 | c.1383G>A p.M461I | Missense Mutation (SNP) | VAF 138/259 reads (53%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1467855177, COSV65330342; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2896G>A p.A966T | Missense Mutation (SNP) | VAF 108/206 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.089); catalogued as rs375424635; called by muse, mutect2, varscan2
- RAB11FIP4 | c.58C>A p.R20S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs1359923820; called by muse, mutect2, varscan2
- RACK1 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV59318629; called by muse, varscan2
- RAD54L | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 66/845 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as COSV100914848; called by muse, mutect2
- RAG1 | c.2752C>T p.R918C | Missense Mutation (SNP) | VAF 213/448 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs753962790; called by muse, mutect2, varscan2
- RANBP9 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 74/149 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs780793088, COSV50580211; called by muse, mutect2, varscan2
- RAPSN | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 252/500 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs753956536; called by muse, mutect2, varscan2
- RASA3 | c.1806G>A p.W602* | Nonsense Mutation (SNP) | VAF 12/304 reads (4%) | catalogued as rs772178234; called by muse, mutect2
- RASA3 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 156/338 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61863639; called by muse, mutect2, varscan2
- RBM4B | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 168/344 reads (49%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); catalogued as rs776465986; called by muse, mutect2, varscan2
- REC8 | c.827del p.P276Rfs*142 | Frame Shift Del (DEL) | VAF 34/48 reads (71%) | catalogued as rs766853930; called by mutect2, varscan2
- REP15 | c.177_179del p.F59del | In Frame Del (DEL) | VAF 52/118 reads (44%) | catalogued as rs758634910; called by pindel, varscan2
- RERE | c.3808C>T p.R1270C | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs368654266; called by muse, mutect2, varscan2
- RESF1 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 91/167 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs754040228; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 47/96 reads (49%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS12 | c.3870dup p.G1291Rfs*45 | Frame Shift Ins (INS) | VAF 30/75 reads (40%) | catalogued as rs751982308; called by mutect2, varscan2
- RGS19 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755556137; called by muse, mutect2, varscan2
- RIC8B | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62694660; called by muse, mutect2, varscan2
- RMC1 | c.1067T>G p.L356R | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV52570821; called by muse, mutect2, varscan2
- RNF112 | c.1868A>G p.D623G | Missense Mutation (SNP) | VAF 86/158 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.825); catalogued as COSV71327067; called by muse, mutect2, varscan2
- RNF115 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 165/297 reads (56%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs186281231, COSV65165090; called by muse, mutect2, varscan2
- RNF187 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 153/244 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1201648729, COSV59959895; called by muse, mutect2, varscan2
- RNF213 | c.12860G>A p.R4287Q | Missense Mutation (SNP) | VAF 163/294 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as rs200034624, COSV60403772; called by muse, mutect2, varscan2
- RNF216 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 83/197 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1314779582, COSV66292442; called by muse, mutect2, varscan2
- RP1L1 | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 41/666 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs758393932, COSV66758516; called by muse, mutect2
- RPE65 | c.597T>A p.N199K | Missense Mutation (SNP) | VAF 185/336 reads (55%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs141527042, COSV52014131; called by muse, mutect2, varscan2
- RPN1 | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 107/234 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1356368738; called by muse, mutect2, varscan2
- RRM1 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 152/294 reads (52%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.072); catalogued as rs772263282; called by muse, mutect2, varscan2
- RRP1 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.028); catalogued as rs1428445931, COSV71856992; called by muse, varscan2
- RSF1 | c.1158del p.K386Nfs*6 | Frame Shift Del (DEL) | VAF 63/164 reads (38%) | catalogued as rs1451848162, COSV100408029; called by mutect2, pindel, varscan2
- RXFP3 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs769933125; called by muse, mutect2, varscan2
- RYR1 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 248/496 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.782); catalogued as rs748318655, COSV100615705, COSV62107125; called by muse, mutect2, varscan2
1,961 further variants in this file (1,081 protein-altering or splice-affecting, 513 silent, 367 other) are not listed here.
